Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NB-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular
fibrolamellar 8171/3

Site: Liver C22.0

9/12/12

DIAGNOSIS:

A. Lymph node, cystic duct, biopsy: A single cystic duct lymph node is negative for tumor.

B. Cystic duct stump, excision: Negative for tumor.

C. Liver, segments VI and VII, polysegmentectomy: Fibrolamellar hepatocellular carcinoma is identified forming a lobulated mass (10.2 x 8.3 x 7.4 cm). The tumor is confined to the liver. The liver parenchyma surgical resection margin is negative for tumor (minimum tumor free margin, 0.5 cm). Macroscopic large vessel invasion is absent. Microscopic invasion is absent. The non-neoplastic hepatic parenchyma is unremarkable.

D. Lymph nodes, hepatoduodenal ligament, biopsy: Multiple (10) hepatoduodenal ligament lymph nodes are negative for tumor.

With available surgical material, [AJCC pT1N0] (7th edition,

Photographed.

Source: NCI Genomic Data Commons file 90138b85-1020-44bb-b633-eff4f8012f2a (TCGA-DD-A4NB.963CA9F8-DA47-4E2E-892E-14E7AB0EB76E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).